Somatic mutation profile of tumor specimen MMRF_2339_1_BM_CD138pos (aliquot MMRF_2339_1_BM_CD138pos_T1_KHS5U_L11018) from MMRF case MMRF_2339, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.7 years (19,611 days).
Specimen MMRF_2339_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cad03961-9539-4192-941c-4c798383f9fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2339_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2339_1_PB_Whole_C2_KHS5U_L11019; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cfa8bd3-1780-41a2-8d52-ed9895756cc2

The open-access MAF lists 84 somatic variants for this specimen: 30 protein-altering or splice-affecting, 12 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 21, Intron 14, Silent 12, 3'Flank 2, 5'Flank 2, 5'UTR 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PIM1 | c.72G>C p.K24N | Missense Mutation (SNP) | VAF 78/147 reads (53%) | hotspot (GDC flag); SIFT tolerated (0.48); PolyPhen benign (0.062); catalogued as COSV65164988, COSV65166078, COSV65166386; called by muse, mutect2, varscan2
- ARHGEF10 | c.3215G>T p.S1072I (on ENST00000398564; = p.S1047I on NM_014629.4) | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV50658814; called by muse, mutect2
- HCAR1 | c.332C>A p.A111E | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV100811620; called by muse, mutect2, varscan2
- IGLV3-1 | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.174); catalogued as rs369867568; called by muse, varscan2
- IGLV3-1 | c.131A>G p.D44G | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs774199094; called by muse, varscan2
- INPP4B | c.1018G>T p.V340F | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs376658791; called by muse, mutect2, varscan2
- KIF22 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 128/286 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.746); catalogued as rs891464618; called by muse, mutect2, varscan2
- MAST1 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 15/276 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1367338510; called by muse, mutect2
- PRLHR | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV53305359; called by muse, mutect2, varscan2
- RPTN | c.1391G>A p.G464D | Missense Mutation (SNP) | VAF 128/376 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs1159442556, COSV60169076; called by muse, mutect2, varscan2
- RTP1 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 128/258 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV56618662; called by muse, mutect2, varscan2
- SAMD4A | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51878946; called by muse, mutect2, varscan2
- SYT16 | c.1024T>C p.S342P | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1249938019, COSV70858845; called by muse, mutect2, varscan2
- TTN | c.83984C>T p.P27995L (on ENST00000591111; = p.P20571L on NM_003319.4) | Missense Mutation (SNP) | VAF 43/119 reads (36%) | PolyPhen benign (0.387); catalogued as COSV60292771; called by muse, mutect2, varscan2
- ZNF582 | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV100019015; called by muse, mutect2
- ARMC8 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 90/226 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- C3 | c.3817T>A p.F1273I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- C7orf26 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2
- CRYBA2 | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- DLGAP1 | c.1634T>C p.V545A | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH9 | c.13414C>A p.P4472T | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.271); called by muse, mutect2
- DSCAM | c.3947C>A p.A1316E | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- FBN3 | c.752G>A p.C251Y | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JAG1 | c.964T>A p.C322S | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEC1 | c.338A>G p.E113G | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MATN3 | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MGAM | c.2798A>C p.N933T | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NAALADL2 | c.866G>T p.R289M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- UTP15 | c.27T>G p.I9M | Missense Mutation (SNP) | VAF 5/145 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2
- ABCC10 | c.1332C>T p.I444= (on ENST00000372530 / NM_001198934.2; = p.I401= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/348 reads (5%) | catalogued as COSV55094151; called by muse, mutect2
- CNDP1 | c.1380C>T p.I460= | Silent (SNP) | VAF 49/133 reads (37%) | catalogued as rs774635198, COSV62593188, COSV62595636; called by muse, mutect2, varscan2
- DNAH5 | c.11463G>A p.T3821= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as rs200744540, COSV54212941; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DUOX1 | c.4008C>T p.I1336= | Silent (SNP) | VAF 66/143 reads (46%) | called by muse, mutect2, varscan2
- IGKV1-6 | c.87T>G p.S29= | Silent (SNP) | VAF 50/126 reads (40%) | catalogued as rs1287833844; called by muse, varscan2
- KCNJ2 | c.18C>A p.T6= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV54663450; called by muse, mutect2, varscan2
- MMP11 | c.129C>T p.A43= | Silent (SNP) | VAF 48/97 reads (49%) | catalogued as rs768284130; called by muse, mutect2, varscan2
- PDGFD | c.768A>G p.S256= | Silent (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2
- PRKDC | c.8223G>A p.L2741= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs1414292547, COSV58047931; called by muse, mutect2, varscan2
- RXFP2 | c.1510C>T p.L504= | Silent (SNP) | VAF 51/125 reads (41%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.2412G>A p.E804= | Silent (SNP) | VAF 16/260 reads (6%) | called by muse, mutect2
- ZNF117 | c.1161T>C p.N387= | Silent (SNP) | VAF 39/128 reads (30%) | catalogued as rs1342992119, COSV99031683; called by muse, mutect2, varscan2
- AADACL3 | c.*1768T>A | 3'UTR (SNP) | VAF 70/163 reads (43%) | called by muse, mutect2, varscan2
- ABCC9 | c.406+1533C>G | Intron (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- AFF3 | chr2:100106095 C>T | 5'Flank (SNP) | VAF 118/263 reads (45%) | called by muse, mutect2, varscan2
- AGO2 | c.*601A>G | 3'UTR (SNP) | VAF 57/179 reads (32%) | called by muse, mutect2, varscan2
- ARRB1 | c.*1817A>T | 3'UTR (SNP) | VAF 65/96 reads (68%) | called by muse, mutect2, varscan2
- CLDN1 | c.*1368C>T | 3'UTR (SNP) | VAF 6/56 reads (11%) | called by mutect2, varscan2
- CRISP2 | c.515+117G>T | Intron (SNP) | VAF 18/58 reads (31%) | catalogued as COSV59257376; called by muse, mutect2, varscan2
- DPM2 | c.4-94A>G | Intron (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- DRGX | c.*379A>T | 3'UTR (SNP) | VAF 47/95 reads (49%) | called by muse, mutect2, varscan2
- EEF2K | c.*17C>T | 3'UTR (SNP) | VAF 108/384 reads (28%) | catalogued as rs200860995; called by muse, mutect2, varscan2
- ERLIN2 | c.425-2127G>A | Intron (SNP) | VAF 59/135 reads (44%) | catalogued as rs1485077387; called by muse, mutect2, varscan2
- EXOC3 | c.-160G>A | 5'UTR (SNP) | VAF 6/18 reads (33%) | catalogued as rs1430955141; called by muse, mutect2
- FAM120C | c.*3197C>T | 3'UTR (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- FAM189B | c.965-97_965-90del | Intron (DEL) | VAF 38/175 reads (22%) | called by mutect2, pindel*, varscan2*
- FMN2 | c.*464A>C | 3'UTR (SNP) | VAF 41/100 reads (41%) | called by muse, mutect2, varscan2
- FRG1EP | n.446G>A | RNA (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- GALK1 | c.-52C>A | 5'UTR (SNP) | VAF 10/15 reads (67%) | called by muse, mutect2, varscan2
- GSTP1 | c.233-81C>A | Intron (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- HHIP | c.*5374T>C | 3'UTR (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- INTS3 | c.432+78_432+86del | Intron (DEL) | VAF 25/51 reads (49%) | called by mutect2, pindel, varscan2
- KCTD9 | c.*1141A>G | 3'UTR (SNP) | VAF 23/229 reads (10%) | called by muse, mutect2, varscan2
- KDM4D | c.*58G>A | 3'UTR (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- KLHDC10 | c.*4772G>A | 3'UTR (SNP) | VAF 53/104 reads (51%) | catalogued as rs1051759119; called by muse, mutect2, varscan2
- LTB | c.209-49G>A | Intron (SNP) | VAF 54/103 reads (52%) | catalogued as rs375282274; called by muse, mutect2, varscan2
- MAP4K4 | chr2:101892978 T>C | 3'Flank (SNP) | VAF 13/204 reads (6%) | called by muse, mutect2
- MARCHF3 | c.*1593C>A | 3'UTR (SNP) | VAF 35/94 reads (37%) | called by muse, mutect2, varscan2
- MGAM | c.4618+1929C>G | Intron (SNP) | VAF 27/74 reads (36%) | catalogued as rs1446650005; called by muse, mutect2, varscan2
- MIEN1 | c.265-15A>T | Intron (SNP) | VAF 42/84 reads (50%) | called by muse, mutect2, varscan2
- MRNIP | c.538-27G>A | Intron (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2
- OSBP2 | c.*247C>T | 3'UTR (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- PGBD5 | chr1:230322931 G>A | 3'Flank (SNP) | VAF 76/176 reads (43%) | catalogued as rs764383016; called by muse, mutect2, varscan2
- PMP2 | c.*858C>A | 3'UTR (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- PRDM16 | c.*1031C>T | 3'UTR (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- SLC4A2 | c.-63-203G>A | Intron (SNP) | VAF 12/257 reads (5%) | catalogued as rs1455477184; called by muse, mutect2
- SNORD114-31 | chr14:100990010 A>T | 5'Flank (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2
- TLX1 | c.*316G>A | 3'UTR (SNP) | VAF 48/84 reads (57%) | called by muse, mutect2, varscan2
- TMX4 | c.*2853A>C | 3'UTR (SNP) | VAF 23/63 reads (37%) | called by muse, mutect2, varscan2
- TNRC6A | c.3695-40G>T | Intron (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- TRHDE | c.*316T>C | 3'UTR (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- USP20 | c.*321A>G | 3'UTR (SNP) | VAF 60/113 reads (53%) | called by muse, mutect2, varscan2
- ZC4H2 | c.399-82G>A | Intron (SNP) | VAF 25/25 reads (100%) | called by muse, mutect2, varscan2
- ZNF583 | c.*281G>A | 3'UTR (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
